Somatic mutation profile of tumor specimen CDDP-A8B0-TTP1-C (aliquot CDDP-A8B0-TTP1-C-1-0-D-A500-36) from CDDP_EAGLE case CDDP-A8B0, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma with mixed subtypes; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66 years.
Specimen CDDP-A8B0-TTP1-C: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9c80f8ff-226e-49a1-b8c0-2a1099f56204.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen CDDP-A8B0-NC1-A (Buccal Cell Normal), aliquot CDDP-A8B0-NC1-A-1-0-D-A500-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5a1b5769-e296-4ee7-9ad7-5890f2bef6c3

The open-access MAF lists 625 somatic variants for this specimen: 429 protein-altering or splice-affecting, 121 silent, 75 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 370, Silent 121, Intron 28, Nonsense Mutation 28, RNA 16, 3'UTR 14, Splice Site 9, Frame Shift Del 9, 5'UTR 7, Splice Region 6, 3'Flank 6, Frame Shift Ins 5.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.924G>T p.W308C | Missense Mutation (SNP) | VAF 32/38 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1313845, CM1314422, CM981871, COSV58821324, COSV58824598; called by muse, varscan2
- TP53 | c.836G>A p.G279E | Missense Mutation (SNP) | VAF 284/385 reads (74%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1064793881, COSV52677880, COSV52851240; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- A2ML1 | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 78/133 reads (59%) | SIFT tolerated (0.09); PolyPhen benign (0.007); catalogued as COSV55287096; called by muse, mutect2, varscan2
- AC002094.3 | c.341G>T p.R114L | Missense Mutation (SNP) | VAF 36/139 reads (26%) | SIFT tolerated (0.75); PolyPhen benign (0); catalogued as rs782475720; called by muse, mutect2, varscan2
- ADAM9 | c.940G>T p.G314* | Nonsense Mutation (SNP) | VAF 137/417 reads (33%) | catalogued as COSV101166036; called by muse, mutect2, varscan2
- ADGRA1 | c.188C>A p.A63E | Missense Mutation (SNP) | VAF 18/50 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.602); catalogued as COSV101192750; called by muse, mutect2, varscan2
- ADGRB3 | c.3430G>T p.V1144F | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.462); catalogued as COSV99486457; called by muse, mutect2, varscan2
- ADGRF2 | c.318C>A p.H106Q (on ENST00000296862 / NM_001368115.2; = p.H38Q on NM_153839.7) | Missense Mutation (SNP) | VAF 58/167 reads (35%) | SIFT tolerated (0.77); PolyPhen benign (0.011); catalogued as COSV57288263; called by muse, mutect2, varscan2
- ADGRF2 | c.1460G>T p.C487F (on ENST00000296862 / NM_001368115.2; = p.C419F on NM_153839.7) | Missense Mutation (SNP) | VAF 64/219 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1181127159; called by muse, mutect2, varscan2
- AGBL4 | c.982C>A p.H328N | Missense Mutation (SNP) | VAF 97/122 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as COSV100484219; called by muse, mutect2, varscan2
- ALOXE3 | c.1879G>C p.D627H | Missense Mutation (SNP) | VAF 101/127 reads (80%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.841); catalogued as rs1489092454; called by muse, mutect2, varscan2
- ALPK2 | c.6055C>T p.R2019W | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as rs546455740; called by muse, mutect2, varscan2
- ANKRD30A | c.3067G>C p.E1023Q (on ENST00000611781; = p.E967Q on NM_052997.2) | Missense Mutation (SNP) | VAF 34/70 reads (49%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.981); catalogued as rs375945698; called by muse, mutect2, varscan2
- ANKRD34C | c.715C>A p.L239I | Missense Mutation (SNP) | VAF 44/154 reads (29%) | SIFT tolerated (0.2); PolyPhen benign (0.096); catalogued as COSV69854727; called by muse, mutect2
- ANKS1B | c.1986G>C p.K662N | Missense Mutation (SNP) | VAF 28/181 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.006); catalogued as COSV100242366; called by muse, mutect2, varscan2
- APBA2 | c.945C>G p.H315Q | Missense Mutation (SNP) | VAF 91/149 reads (61%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV101382255, COSV68794281; called by muse, mutect2, varscan2
- ARHGAP29 | c.1316A>T p.Q439L | Missense Mutation (SNP) | VAF 86/107 reads (80%) | SIFT deleterious (0); PolyPhen possibly damaging (0.474); catalogued as COSV53114981; called by muse, mutect2, varscan2
- ARMCX4 | c.706C>G p.L236V (on ENST00000433011; = p.L132V on NM_001256155.2) | Missense Mutation (SNP) | VAF 54/64 reads (84%) | SIFT tolerated (0.11); PolyPhen benign (0.231); catalogued as rs1556007711; called by muse, mutect2, varscan2
- B3GNT3 | c.230C>T p.P77L | Missense Mutation (SNP) | VAF 111/145 reads (77%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as rs753539520; called by muse, mutect2, varscan2
- CACNA1B | c.6325G>A p.G2109S | Missense Mutation (SNP) | VAF 30/38 reads (79%) | SIFT tolerated (0.08); PolyPhen benign (0.288); catalogued as rs1216208425; called by muse, mutect2, varscan2
- CALCOCO2 | c.189G>A p.W63* | Nonsense Mutation (SNP) | VAF 53/80 reads (66%) | catalogued as rs1369158168; called by muse, mutect2, varscan2
- CALHM1 | c.182C>T p.P61L | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as COSV100324214; called by muse, mutect2, varscan2
- CARD9 | c.811G>T p.G271W | Missense Mutation (SNP) | VAF 196/229 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.793); catalogued as COSV59997527; called by muse, mutect2, varscan2
- CCBE1 | c.994C>T p.P332S | Missense Mutation (SNP) | VAF 160/264 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV67949676; called by muse, mutect2, varscan2
- CD81 | c.631G>A p.V211M | Missense Mutation (SNP) | VAF 31/163 reads (19%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.96); catalogued as rs139884987; called by muse, mutect2, varscan2
- CDK17 | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 17/199 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1188180352; called by muse, mutect2
- CEP164 | c.2635G>T p.E879* | Nonsense Mutation (SNP) | VAF 165/242 reads (68%) | catalogued as COSV54038400; called by muse, mutect2, varscan2
- CHAT | c.1262G>C p.W421S | Missense Mutation (SNP) | VAF 70/221 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM119378; called by muse, mutect2, varscan2
- CHL1 | c.352G>T p.A118S | Missense Mutation (SNP) | VAF 54/69 reads (78%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs779131290; called by muse, mutect2, varscan2
- CHRM3 | c.100G>A p.V34I | Missense Mutation (SNP) | VAF 119/198 reads (60%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs201042655, COSV55079216; called by muse, mutect2, varscan2
- CLCC1 | c.1126C>G p.P376A (on ENST00000356970 / NM_001377464.1; = p.P326A on NM_015127.5) | Missense Mutation (SNP) | VAF 47/65 reads (72%) | SIFT tolerated (0.05); PolyPhen benign (0.013); catalogued as rs765297839; called by muse, mutect2, varscan2
- CLEC12B | c.172G>T p.V58L | Missense Mutation (SNP) | VAF 69/137 reads (50%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.856); catalogued as COSV58863571; called by muse, mutect2, varscan2
- CLEC14A | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 25/151 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV60564649; called by muse, mutect2, varscan2
- CLEC16A | c.1878G>A p.M626I | Missense Mutation (SNP) | VAF 26/90 reads (29%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as rs772417435; called by muse, mutect2, varscan2
- CNTNAP5 | c.955G>T p.G319W | Missense Mutation (SNP) | VAF 8/63 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV70510352; called by muse, mutect2, varscan2
- COL1A2 | c.1684G>C p.G562R | Missense Mutation (SNP) | VAF 82/252 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CM920206; called by muse, mutect2, varscan2
- COL20A1 | c.2716C>A p.R906S | Missense Mutation (SNP) | VAF 30/109 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58914276; called by muse, mutect2, varscan2
- COL22A1 | c.480C>A p.D160E | Missense Mutation (SNP) | VAF 50/119 reads (42%) | SIFT tolerated (0.8); PolyPhen benign (0.012); catalogued as COSV57339352, COSV57348952; called by muse, mutect2, varscan2
- CPEB1 | c.1385G>C p.R462P (on ENST00000617958; = p.R397P on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/67 reads (51%) | SIFT tolerated (0.05); PolyPhen benign (0.041); catalogued as COSV99917357; called by muse, mutect2, varscan2
- CSMD1 | c.6337G>T p.E2113* (on ENST00000520002; = p.E2112* on NM_033225.6) | Nonsense Mutation (SNP) | VAF 61/131 reads (47%) | catalogued as COSV59352278, COSV59392608; called by muse, mutect2, varscan2
- CSMD3 | c.8060C>A p.P2687H (on ENST00000297405 / NM_001363185.1; = p.P2583H on NM_052900.3) | Missense Mutation (SNP) | VAF 332/553 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV52122249; called by muse, mutect2, varscan2
- CSMD3 | c.161C>G p.T54R | Missense Mutation (SNP) | VAF 171/591 reads (29%) | SIFT tolerated, low confidence (0.34); PolyPhen benign (0.052); catalogued as COSV52113522; called by muse, mutect2, varscan2
- DBX2 | c.148C>A p.P50T | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.05); PolyPhen benign (0.284); catalogued as COSV60339724; called by muse, varscan2
- DEFA3 | c.171T>A p.H57Q | Missense Mutation (SNP) | VAF 72/535 reads (13%) | SIFT tolerated (0.13); PolyPhen benign (0.001); catalogued as rs1299506048; called by muse, mutect2, varscan2
- DGKB | c.1683G>T p.R561S | Missense Mutation (SNP) | VAF 28/120 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99336291, COSV99337606; called by muse, mutect2, varscan2
- DIP2A | c.1699G>T p.V567L | Missense Mutation (SNP) | VAF 55/91 reads (60%) | SIFT deleterious (0.01); PolyPhen benign (0.394); catalogued as rs754663374; called by muse, mutect2, varscan2
- DIP2A | c.3946G>A p.V1316I | Missense Mutation (SNP) | VAF 90/133 reads (68%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.987); catalogued as rs1196206605; called by muse, mutect2, varscan2
- DMD | c.3826G>A p.E1276K | Missense Mutation (SNP) | VAF 49/66 reads (74%) | SIFT tolerated (0.05); PolyPhen benign (0.014); catalogued as rs1368655785; called by muse, mutect2, varscan2
- DPP10 | c.1740C>G p.F580L | Missense Mutation (SNP) | VAF 44/65 reads (68%) | SIFT deleterious (0); PolyPhen possibly damaging (0.846); catalogued as COSV59667781; called by muse, mutect2, varscan2
- DPYS | c.1462G>T p.V488L | Missense Mutation (SNP) | VAF 143/556 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as COSV60906729; called by muse, mutect2, varscan2
- EARS2 | c.1195G>T p.V399L | Missense Mutation (SNP) | VAF 32/99 reads (32%) | SIFT tolerated (0.17); PolyPhen benign (0.001); catalogued as COSV71942958; called by muse, mutect2, varscan2
- EDN1 | c.360G>C p.W120C | Missense Mutation (SNP) | VAF 83/237 reads (35%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.747); catalogued as COSV65081016; called by muse, mutect2, varscan2
- EFCAB8 | c.834G>A p.M278I | Missense Mutation (SNP) | VAF 96/176 reads (55%) | SIFT tolerated (0.09); PolyPhen benign (0); catalogued as COSV68699778; called by muse, mutect2, varscan2
- EIF3B | c.1797G>C p.K599N | Missense Mutation (SNP) | VAF 14/78 reads (18%) | SIFT tolerated (0.16); PolyPhen benign (0.137); catalogued as COSV62804882; called by muse, mutect2, varscan2
- EMC10 | c.712A>T p.M238L | Missense Mutation (SNP) | VAF 26/143 reads (18%) | SIFT tolerated (0.43); PolyPhen benign (0.114); catalogued as rs1417180202; called by muse, mutect2, varscan2
- EPHA6 | c.2573G>A p.R858Q (on ENST00000389672 / NM_001080448.3; = p.R250Q on NM_173655.4) | Missense Mutation (SNP) | VAF 59/70 reads (84%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); catalogued as rs776617495, COSV67571163; called by muse, mutect2, varscan2
- EPSTI1 | c.920G>T p.C307F (on ENST00000398762 / NM_001330543.2; = p.C296F on NM_033255.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/46 reads (54%) | SIFT tolerated (0.64); PolyPhen benign (0.003); catalogued as COSV58046456; called by muse, mutect2
- EPX | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 43/228 reads (19%) | SIFT tolerated (0.79); PolyPhen benign (0.005); catalogued as rs750422182, COSV56599166; called by muse, mutect2, varscan2
- FAM124A | c.361C>A p.R121S (on ENST00000322475 / NM_001242312.2; = p.R157S on NM_145019.4) | Missense Mutation (SNP) | VAF 84/114 reads (74%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.491); catalogued as rs866807267; called by muse, mutect2, varscan2
- FAM13C | c.761C>A p.P254H | Missense Mutation (SNP) | VAF 118/247 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV53249530; called by muse, mutect2, varscan2
- FASTKD1 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 93/142 reads (65%) | SIFT deleterious (0.04); PolyPhen benign (0.156); catalogued as rs1257138116, COSV70006980; called by muse, mutect2, varscan2
- FBLN5 | c.1296A>C p.R432S | Missense Mutation (SNP) | VAF 34/486 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.528); catalogued as COSV99969518; called by muse, mutect2
- FBXO31 | c.1354G>T p.V452L | Missense Mutation (SNP) | VAF 26/39 reads (67%) | SIFT deleterious (0.04); PolyPhen benign (0.369); catalogued as rs759819249; called by muse, mutect2, varscan2
- FER1L5 | c.2828G>T p.R943L (on ENST00000623019; = p.R950L on NM_001293083.2) | Missense Mutation (SNP) | VAF 8/84 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.931); catalogued as rs781178713, COSV67606770; called by mutect2, varscan2
- FHAD1 | c.341G>T p.G114V | Missense Mutation (SNP) | VAF 28/165 reads (17%) | SIFT tolerated (0.09); PolyPhen benign (0.102); catalogued as COSV62715195; called by muse, mutect2, varscan2
- GAL3ST3 | c.523G>C p.V175L | Missense Mutation (SNP) | VAF 64/158 reads (41%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.873); catalogued as COSV61749061; called by muse, mutect2, varscan2
- GFRAL | c.169C>A p.P57T | Missense Mutation (SNP) | VAF 9/41 reads (22%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs1429362640, COSV61233367, COSV61235896; called by muse, mutect2, varscan2
- GJB1 | c.116C>A p.A39D | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CD065727, CM0910899, CM994203; called by muse, mutect2, varscan2
- HCN1 | c.329C>A p.S110Y | Missense Mutation (SNP) | VAF 49/255 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57514706; called by muse, varscan2
- HDHD2 | c.632G>C p.G211A | Missense Mutation (SNP) | VAF 116/182 reads (64%) | SIFT tolerated (0.76); PolyPhen benign (0.014); catalogued as COSV56075211; called by muse, mutect2, varscan2
- HRH4 | c.707G>T p.R236I | Missense Mutation (SNP) | VAF 35/241 reads (15%) | SIFT tolerated (0.19); PolyPhen benign (0.003); catalogued as COSV56928904; called by muse, mutect2, varscan2
- IGF2R | c.3622G>T p.V1208L | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV63633134; called by muse, mutect2, varscan2
- IGHV2OR16-5 | c.8C>T p.T3M | Missense Mutation (SNP) | VAF 12/94 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as rs780442065; called by mutect2, varscan2
- IGLV3-1 | c.105G>T p.Q35H | Missense Mutation (SNP) | VAF 281/331 reads (85%) | SIFT deleterious (0); PolyPhen benign (0.411); catalogued as rs550143178; called by muse, mutect2, varscan2
- INHBE | c.239A>T p.Q80L | Missense Mutation (SNP) | VAF 76/114 reads (67%) | SIFT deleterious (0.02); PolyPhen benign (0.422); catalogued as rs1220991611; called by muse, mutect2, varscan2
- ISLR2 | c.1607G>A p.G536E | Missense Mutation (SNP) | VAF 49/117 reads (42%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.63); catalogued as rs765610942; called by muse, mutect2, varscan2
- IZUMO3 | c.464G>C p.R155T (on ENST00000543880 / NM_001365008.2; = p.R149T on NM_001271706.1) | Missense Mutation (SNP) | VAF 53/77 reads (69%) | SIFT tolerated (0.17); PolyPhen benign (0.412); catalogued as COSV69048517; called by muse, mutect2, varscan2
- KCNB1 | c.1408G>A p.E470K | Missense Mutation (SNP) | VAF 42/69 reads (61%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100870471; called by muse, mutect2, varscan2
- KDM4D | c.523G>A p.V175I | Missense Mutation (SNP) | VAF 180/289 reads (62%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.942); catalogued as rs148400811; called by muse, mutect2, varscan2
- KDM5B | c.2840G>T p.G947V | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.566); catalogued as COSV52507434, COSV99349838; called by muse, mutect2
- KDM6B | c.1033G>C p.E345Q | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.979); catalogued as COSV54685282; called by muse, mutect2, varscan2
- KIAA1755 | c.1637C>G p.A546G | Missense Mutation (SNP) | VAF 55/81 reads (68%) | SIFT tolerated (0.1); PolyPhen benign (0.054); catalogued as COSV54077453; called by muse, mutect2, varscan2
- KIF3A | c.1223G>A p.R408K | Missense Mutation (SNP) | VAF 54/114 reads (47%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV101109500, COSV66413265; called by muse, varscan2
- KRTAP16-1 | c.838C>A p.R280S | Missense Mutation (SNP) | VAF 19/225 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.333); catalogued as COSV66939507; called by muse, mutect2
- LCT | c.3817G>C p.E1273Q | Missense Mutation (SNP) | VAF 29/150 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV51548234; called by muse, mutect2, varscan2
- LINGO1 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 43/160 reads (27%) | catalogued as COSV100796527, COSV62436071; called by muse, mutect2, varscan2
- LPAR4 | c.584G>T p.R195L | Missense Mutation (SNP) | VAF 18/31 reads (58%) | SIFT tolerated (0.16); PolyPhen benign (0.138); catalogued as COSV70913115, COSV70913491; called by muse, mutect2, varscan2
- LRFN2 | c.1849C>G p.R617G | Missense Mutation (SNP) | VAF 75/151 reads (50%) | SIFT tolerated (0.4); PolyPhen benign (0.043); catalogued as rs775968133, COSV100600065; called by muse, mutect2, varscan2
- LRRC4 | c.947G>C p.R316P | Missense Mutation (SNP) | VAF 23/200 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as COSV50813251; called by muse, mutect2, varscan2
- LZTR1 | c.720G>A p.M240I | Missense Mutation (SNP) | VAF 165/198 reads (83%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.492); catalogued as rs1466927211; called by muse, mutect2, varscan2
- MAP1B | c.2215G>T p.A739S | Missense Mutation (SNP) | VAF 113/184 reads (61%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV57103410; called by muse, varscan2
- MAPT | c.62G>T p.G21V | Missense Mutation (SNP) | VAF 193/294 reads (66%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.913); catalogued as rs781076528; called by muse, mutect2, varscan2
- MMRN1 | c.520G>A p.V174M | Missense Mutation (SNP) | VAF 121/283 reads (43%) | SIFT tolerated (0.56); PolyPhen benign (0.001); catalogued as rs1560579071, COSV53339794; called by muse, mutect2, varscan2
- MYF6 | c.284G>T p.R95L | Missense Mutation (SNP) | VAF 53/415 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57352231; called by muse, mutect2, varscan2
- NAV3 | c.3496G>A p.V1166I | Missense Mutation (SNP) | VAF 63/347 reads (18%) | SIFT tolerated (0.49); PolyPhen benign (0.343); catalogued as rs757020983, COSV57088033; called by muse, mutect2, varscan2
- NAV3 | c.4951G>T p.A1651S | Missense Mutation (SNP) | VAF 21/108 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.031); catalogued as COSV57083617; called by muse, mutect2, varscan2
- NEU4 | c.1204G>C p.D402H (on ENST00000391969 / NM_001167602.3; = p.D414H on NM_080741.4) | Missense Mutation (SNP) | VAF 65/105 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs1263656061; called by muse, mutect2, varscan2
- NOBOX | c.1043C>A p.A348D | Missense Mutation (SNP) | VAF 39/98 reads (40%) | SIFT tolerated (0.22); PolyPhen benign (0.026); catalogued as rs1370157582; called by muse, varscan2
- NOX4 | c.18G>T p.R6S | Missense Mutation (SNP) | VAF 65/165 reads (39%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.066); catalogued as COSV54462371; called by muse, mutect2, varscan2
- NRDC | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 10/170 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.741); catalogued as rs1394998217, COSV100703902; called by muse, mutect2
- NUAK2 | c.922G>A p.A308T | Missense Mutation (SNP) | VAF 15/93 reads (16%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as rs770685148; called by muse, mutect2, varscan2
- OR2L3 | c.163C>T p.H55Y | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.905); catalogued as COSV63455495; called by muse, mutect2, varscan2
- OR5B12 | c.520C>A p.H174N | Missense Mutation (SNP) | VAF 89/187 reads (48%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.982); catalogued as COSV56907031; called by muse, mutect2, varscan2
- OR5D14 | c.590C>A p.P197H | Missense Mutation (SNP) | VAF 84/195 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.006); catalogued as COSV100162061; called by muse, mutect2, varscan2
- OR5T1 | c.761G>T p.G254V | Missense Mutation (SNP) | VAF 83/177 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as rs760019236, COSV57303949; called by muse, varscan2
- OR6N1 | c.323G>C p.G108A | Missense Mutation (SNP) | VAF 47/166 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58649060; called by muse, mutect2, varscan2
- PABPC4L | c.1027G>T p.E343* | Nonsense Mutation (SNP) | VAF 40/106 reads (38%) | catalogued as COSV69931694; called by muse, mutect2, varscan2
- PARP8 | c.1426G>T p.A476S | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated, low confidence (0.3); PolyPhen probably damaging (0.956); catalogued as rs370470653; called by muse, mutect2, varscan2
- PCBP3 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 41/51 reads (80%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs775103263; called by muse, mutect2, varscan2
- PCDH18 | c.776C>T p.S259F | Missense Mutation (SNP) | VAF 43/104 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1031924456, COSV61270923; called by muse, mutect2, varscan2
- PDZRN3 | c.1121C>A p.S374Y | Missense Mutation (SNP) | VAF 61/107 reads (57%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV55200275; called by muse, mutect2, varscan2
- PDZRN4 | c.2825G>T p.S942I (on ENST00000402685 / NM_001164595.2; = p.S684I on NM_013377.4) | Missense Mutation (SNP) | VAF 165/263 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV54198248; called by muse, mutect2, varscan2
- PGLYRP2 | c.721C>A p.P241T | Missense Mutation (SNP) | VAF 108/140 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.007); catalogued as COSV52994801; called by muse, mutect2, varscan2
- PIK3CD | c.1242G>T p.A414= | Splice Region (SNP) | VAF 218/248 reads (88%) | catalogued as COSV100740692; called by muse, mutect2, varscan2
- PLEKHA1 | c.961G>T p.A321S | Missense Mutation (SNP) | VAF 26/100 reads (26%) | SIFT tolerated (0.52); PolyPhen benign (0.003); catalogued as COSV64570480; called by muse, mutect2
- POM121L12 | c.123G>T p.Q41H | Missense Mutation (SNP) | VAF 57/276 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.896); catalogued as rs1403727197, COSV68692383; called by muse, mutect2, varscan2
- POM121L2 | c.2269G>T p.G757* | Nonsense Mutation (SNP) | VAF 81/232 reads (35%) | catalogued as COSV66276834; called by muse, mutect2, varscan2
- PRAMEF10 | c.676C>T p.P226S | Missense Mutation (SNP) | VAF 16/22 reads (73%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.545); catalogued as COSV99338944; called by mutect2, varscan2
- PRDM9 | c.2273G>C p.R758P | Missense Mutation (SNP) | VAF 110/662 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.037); catalogued as COSV57004243; called by muse, varscan2
- PRX | c.586C>G p.R196G | Missense Mutation (SNP) | VAF 76/553 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs104894706, CM010393; called by muse, mutect2, varscan2
- PZP | c.3289A>G p.I1097V | Missense Mutation (SNP) | VAF 24/98 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.158); catalogued as rs1394490258; called by muse, mutect2
- RBMXL1 | c.706C>T p.P236S | Missense Mutation (SNP) | VAF 166/210 reads (79%) | SIFT tolerated (0.12); PolyPhen benign (0.197); catalogued as rs1461016774; called by muse, varscan2
- RPL3L | c.688+2T>C p.X230_splice | Splice Site (SNP) | VAF 9/57 reads (16%) | catalogued as rs1411618049; called by muse, mutect2, varscan2
- RYR1 | c.13310C>T p.A4437V | Missense Mutation (SNP) | VAF 53/60 reads (88%) | SIFT tolerated (0.29); PolyPhen benign (0); catalogued as rs1359188943; called by muse, mutect2, varscan2
- RYR3 | c.14581C>T p.R4861C (on ENST00000389232; = p.R4862C on NM_001036.6) | Missense Mutation (SNP) | VAF 7/72 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1309538160; called by muse, mutect2, varscan2
- SCN3A | c.109C>A p.P37T | Missense Mutation (SNP) | VAF 80/334 reads (24%) | SIFT tolerated (0.15); PolyPhen benign (0.068); catalogued as rs951311700, COSV51818071; called by mutect2, varscan2
- SFRP2 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 68/180 reads (38%) | catalogued as COSV104385900; called by muse, mutect2, varscan2
- SLC22A7 | c.345G>C p.Q115H | Missense Mutation (SNP) | VAF 18/23 reads (78%) | SIFT tolerated (0.66); PolyPhen benign (0.014); catalogued as COSV101000775; called by mutect2, varscan2
- SOX30 | c.431C>A p.P144H | Missense Mutation (SNP) | VAF 121/144 reads (84%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0); catalogued as rs1383930128; called by muse, mutect2, varscan2
- SV2C | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 84/137 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59229887; called by muse, mutect2, varscan2
- TFAP2D | c.646G>T p.G216C | Missense Mutation (SNP) | VAF 73/140 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50452900; called by muse, varscan2
- TMEM200A | c.626C>G p.T209R | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.442); catalogued as rs145944902; called by muse, mutect2, varscan2
- TMEM200C | c.275C>T p.A92V | Missense Mutation (SNP) | VAF 32/111 reads (29%) | SIFT tolerated (0.31); PolyPhen benign (0.001); catalogued as rs929706243; called by muse, mutect2, varscan2
- TMPRSS5 | c.874G>T p.E292* | Nonsense Mutation (SNP) | VAF 34/145 reads (23%) | catalogued as COSV55425107; called by muse, mutect2, varscan2
- TRBV3-1 | c.266A>G p.D89G | Missense Mutation (SNP) | VAF 30/98 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.939); catalogued as rs1275066818; called by muse, varscan2
- TRIM21 | c.320G>T p.G107V | Missense Mutation (SNP) | VAF 105/159 reads (66%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV99587753; called by muse, mutect2, varscan2
- TTN | c.54394G>C p.E18132Q (on ENST00000591111; = p.E10708Q on NM_003319.4) | Missense Mutation (SNP) | VAF 49/80 reads (61%) | PolyPhen possibly damaging (0.787); catalogued as COSV60005752; called by muse, mutect2, varscan2
- TYR | c.117G>T p.W39C | Missense Mutation (SNP) | VAF 222/459 reads (48%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as CM100975, COSV54479427; called by muse, mutect2, varscan2
- UNC5C | c.1957G>A p.D653N | Missense Mutation (SNP) | VAF 42/295 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.118); catalogued as COSV101497926; called by muse, mutect2, varscan2
- USH2A | c.3806T>A p.L1269Q | Missense Mutation (SNP) | VAF 12/174 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.163); catalogued as COSV100229226; called by muse, mutect2
- USP15 | c.1265C>T p.A422V (on ENST00000280377 / NM_001351159.2; = p.A393V on NM_006313.3 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 12/95 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54799471; called by muse, mutect2, varscan2
- UTRN | c.6796G>T p.V2266F | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.237); catalogued as rs116253225, COSV62327988; called by muse, mutect2, varscan2
- ZFHX4 | c.4738G>T p.V1580F | Missense Mutation (SNP) | VAF 187/347 reads (54%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.944); catalogued as COSV51472224; called by muse, mutect2, varscan2
- ZFY | c.1958C>G p.T653R | Missense Mutation (SNP) | VAF 154/190 reads (81%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs766849104, COSV50083462; called by muse, mutect2, varscan2
- ZNF670 | c.1123A>T p.S375C | Missense Mutation (SNP) | VAF 47/189 reads (25%) | SIFT deleterious (0.02); PolyPhen benign (0.067); catalogued as COSV63609144; called by muse, mutect2, varscan2
- AASS | c.155A>T p.N52I | Missense Mutation (SNP) | VAF 216/439 reads (49%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- ABCA13 | c.11537C>A p.S3846Y | Missense Mutation (SNP) | VAF 29/111 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ABCA3 | c.1624G>T p.G542* | Nonsense Mutation (SNP) | VAF 166/332 reads (50%) | called by muse, mutect2, varscan2
- ABCA6 | c.3333C>G p.F1111L | Missense Mutation (SNP) | VAF 10/59 reads (17%) | SIFT tolerated (0.5); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- ABCB1 | c.1321C>G p.Q441E | Missense Mutation (SNP) | VAF 176/503 reads (35%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- ABHD12 | c.907G>T p.D303Y | Missense Mutation (SNP) | VAF 14/260 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- AC138647.1 | c.222G>T p.E74D | Missense Mutation (SNP) | VAF 91/217 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ACBD5 | c.1469A>T p.Q490L (on ENST00000375888 / NM_001352568.1; = p.Q481L on NM_145698.5 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 124/613 reads (20%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ACOXL | c.1378A>T p.T460S (on ENST00000389811 / NM_001371254.1; = p.T430S on NM_001142807.4) | Missense Mutation (SNP) | VAF 20/112 reads (18%) | SIFT tolerated (0.53); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ACP7 | c.822C>A p.N274K | Missense Mutation (SNP) | VAF 182/203 reads (90%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ACTRT1 | c.551C>A p.A184E | Missense Mutation (SNP) | VAF 122/136 reads (90%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ADAMTS19 | c.2321G>T p.G774V | Missense Mutation (SNP) | VAF 25/64 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- ADCY10 | c.2150G>T p.C717F | Missense Mutation (SNP) | VAF 133/202 reads (66%) | SIFT deleterious (0.01); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- AGAP6 | c.1350G>T p.M450I (on ENST00000374056 / NM_001365867.1; = p.M473I on NM_001077665.2) | Missense Mutation (SNP) | VAF 283/838 reads (34%) | SIFT tolerated (0.53); PolyPhen benign (0.027); called by muse, mutect2, varscan2
- AGMO | c.65C>G p.T22R | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- AHCTF1 | c.5411G>C p.G1804A (on ENST00000366508; = p.G1778A on NM_015446.5) | Missense Mutation (SNP) | VAF 207/377 reads (55%) | SIFT tolerated (0.08); PolyPhen benign (0.291); called by muse, mutect2, varscan2
- AHNAK2 | c.10325A>G p.D3442G | Missense Mutation (SNP) | VAF 77/448 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); called by muse, mutect2, varscan2
- ALKBH8 | c.1938A>T p.R646S | Missense Mutation (SNP) | VAF 58/98 reads (59%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANKRD18A | c.246A>T p.Q82H | Missense Mutation (SNP) | VAF 39/49 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- AOC1 | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 70/183 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- AP5S1 | c.598C>A p.R200S | Missense Mutation (SNP) | VAF 38/44 reads (86%) | SIFT deleterious (0.01); PolyPhen benign (0.133); called by muse, mutect2, varscan2
- ARG2 | c.720C>G p.G240= | Splice Region (SNP) | VAF 49/66 reads (74%) | called by muse, mutect2, varscan2
- ARID5B | c.278A>C p.D93A | Missense Mutation (SNP) | VAF 43/249 reads (17%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.585); called by muse, mutect2
- ARMC4 | c.661G>T p.E221* | Nonsense Mutation (SNP) | VAF 41/216 reads (19%) | called by muse, mutect2, varscan2
- ATP5F1A | c.1654G>A p.E552K | Missense Mutation (SNP) | VAF 13/68 reads (19%) | SIFT tolerated, low confidence (0.7); PolyPhen benign (0); called by muse, mutect2, varscan2
- ATP7A | c.536G>T p.G179V | Missense Mutation (SNP) | VAF 38/69 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ATRNL1 | c.3919A>T p.I1307F | Missense Mutation (SNP) | VAF 43/117 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- BBS12 | c.1783T>A p.W595R | Missense Mutation (SNP) | VAF 36/80 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- BBS12 | c.1871A>G p.Q624R | Missense Mutation (SNP) | VAF 22/68 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.644); called by muse, varscan2
- BIRC6 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.46); called by muse, mutect2, varscan2
- BMS1 | c.1310A>T p.D437V | Missense Mutation (SNP) | VAF 46/163 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.189); called by muse, mutect2, varscan2
- BPIFB3 | c.653-2A>T p.X218_splice | Splice Site (SNP) | VAF 73/113 reads (65%) | called by muse, mutect2, varscan2
- BTBD11 | c.3244G>T p.D1082Y (on ENST00000280758 / NM_001018072.2; = p.D619Y on NM_001017523.2) | Missense Mutation (SNP) | VAF 215/313 reads (69%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- BTNL8 | c.185G>C p.S62T | Missense Mutation (SNP) | VAF 107/336 reads (32%) | SIFT tolerated (0.56); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- C11orf24 | c.523G>T p.G175W | Missense Mutation (SNP) | VAF 57/310 reads (18%) | SIFT tolerated (0.23); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- C9orf57 | c.164-7C>A | Splice Region (SNP) | VAF 82/108 reads (76%) | called by muse, mutect2, varscan2
- CA10 | c.892C>A p.R298S | Missense Mutation (SNP) | VAF 61/86 reads (71%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CA2 | c.508G>T p.G170C | Missense Mutation (SNP) | VAF 166/659 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- CACNG1 | c.148C>A p.H50N | Missense Mutation (SNP) | VAF 62/387 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- CAPN10 | c.1915A>T p.T639S | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT tolerated (0.12); PolyPhen benign (0.303); called by muse, mutect2, varscan2
- CASP4 | c.499G>A p.E167K | Missense Mutation (SNP) | VAF 26/115 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.081); called by muse, mutect2, varscan2
- CCDC175 | c.519G>T p.K173N | Missense Mutation (SNP) | VAF 32/128 reads (25%) | SIFT deleterious (0.01); PolyPhen benign (0.083); called by muse, mutect2, varscan2
- CCNB1 | c.442G>A p.D148N | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- CDC20B | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 64/307 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH26 | c.1614G>T p.L538F | Missense Mutation (SNP) | VAF 59/194 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- CDK14 | c.1134C>A p.N378K (on ENST00000380050 / NM_001287135.2; = p.N360K on NM_012395.3) | Missense Mutation (SNP) | VAF 20/68 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- CDRT15L2 | c.503C>A p.P168Q | Missense Mutation (SNP) | VAF 50/87 reads (57%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.908); called by muse, varscan2
- CELF5 | c.1445G>T p.G482V | Missense Mutation (SNP) | VAF 64/80 reads (80%) | SIFT deleterious (0); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- CEMIP | c.1040_1041insC p.W347Cfs*14 | Frame Shift Ins (INS) | VAF 114/264 reads (43%) | called by mutect2, pindel*, varscan2
- CEP250 | c.5325_5326insGGG p.Q1775_R1776insG | In Frame Ins (INS) | VAF 22/138 reads (16%) | called by mutect2, pindel, varscan2
- CFHR4 | c.1266C>A p.C422* (on ENST00000367416 / NM_001201551.2; = p.C176* on NM_006684.5) | Nonsense Mutation (SNP) | VAF 33/144 reads (23%) | called by muse, mutect2, varscan2
- CGB7 | c.214C>G p.L72V | Missense Mutation (SNP) | VAF 93/351 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- CHD8 | c.3102dup p.E1035Rfs*4 (on ENST00000646647 / NM_001170629.2; = p.E756Rfs*4 on NM_020920.4) | Frame Shift Ins (INS) | VAF 44/148 reads (30%) | called by mutect2, pindel, varscan2
- CHL1 | c.851G>T p.G284V (on ENST00000397491 / NM_001253387.1; = p.G300V on NM_006614.4) | Missense Mutation (SNP) | VAF 75/105 reads (71%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.757); called by muse, mutect2, varscan2
- CLDN18 | c.121dup p.T41Nfs*106 | Frame Shift Ins (INS) | VAF 107/318 reads (34%) | called by mutect2, pindel, varscan2
- CNTN1 | c.840A>T p.E280D | Missense Mutation (SNP) | VAF 84/142 reads (59%) | SIFT tolerated (0.18); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- COL16A1 | c.281G>T p.R94L | Missense Mutation (SNP) | VAF 80/91 reads (88%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- COL27A1 | c.4351G>C p.G1451R | Missense Mutation (SNP) | VAF 32/308 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- COL3A1 | c.3773C>A p.P1258H | Missense Mutation (SNP) | VAF 26/121 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- COL6A3 | c.1538G>T p.R513L | Missense Mutation (SNP) | VAF 41/251 reads (16%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.695); called by muse, mutect2, varscan2
- COL6A5 | c.3832G>T p.G1278W | Missense Mutation (SNP) | VAF 187/225 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- CPNE8 | c.1347G>T p.M449I | Missense Mutation (SNP) | VAF 26/139 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- CPXM2 | c.1611G>T p.Q537H | Missense Mutation (SNP) | VAF 20/62 reads (32%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.722); called by muse, mutect2, varscan2
- CRKL | c.237C>G p.D79E | Missense Mutation (SNP) | VAF 91/208 reads (44%) | SIFT tolerated (0.48); PolyPhen benign (0); called by muse, mutect2, varscan2
- CRYGB | c.76C>A p.L26I | Missense Mutation (SNP) | VAF 159/235 reads (68%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CSMD1 | c.7715G>A p.R2572K (on ENST00000520002; = p.R2571K on NM_033225.6) | Missense Mutation (SNP) | VAF 80/140 reads (57%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.866); called by muse, mutect2, varscan2
- CUX2 | c.1211C>A p.P404H | Missense Mutation (SNP) | VAF 18/177 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- DCAF12L2 | c.782G>A p.S261N | Missense Mutation (SNP) | VAF 75/84 reads (89%) | SIFT tolerated (0.35); PolyPhen benign (0); called by muse, mutect2, varscan2
- DCAF4L2 | c.317G>T p.G106V | Missense Mutation (SNP) | VAF 73/549 reads (13%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- DENND2A | c.1508T>G p.L503R | Missense Mutation (SNP) | VAF 69/145 reads (48%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); called by muse, mutect2, varscan2
- DENND6A | c.1345A>C p.I449L | Missense Mutation (SNP) | VAF 83/107 reads (78%) | SIFT deleterious (0.02); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DIS3 | c.516C>G p.I172M | Missense Mutation (SNP) | VAF 46/76 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); called by muse, mutect2, varscan2
- DLGAP4 | c.1570G>A p.E524K | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.19); called by muse, mutect2, varscan2
- DNAAF2 | c.320C>A p.S107Y | Missense Mutation (SNP) | VAF 276/408 reads (68%) | SIFT deleterious (0.02); PolyPhen benign (0.105); called by muse, mutect2, varscan2
- DNAI2 | c.1189del p.E397Nfs*22 | Frame Shift Del (DEL) | VAF 93/187 reads (50%) | called by mutect2, pindel, varscan2
- DSEL | c.259C>A p.Q87K | Missense Mutation (SNP) | VAF 21/129 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.108); called by muse, mutect2, varscan2
- ENPP3 | c.2431C>G p.R811G | Missense Mutation (SNP) | VAF 25/42 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- ENPP7 | c.1073A>G p.K358R | Missense Mutation (SNP) | VAF 285/334 reads (85%) | SIFT tolerated (0.42); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ERVV-1 | c.1109T>A p.L370H | Missense Mutation (SNP) | VAF 48/70 reads (69%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- FAM184A | c.1752G>T p.Q584H | Missense Mutation (SNP) | VAF 32/73 reads (44%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- FAM184B | c.666G>T p.Q222H | Missense Mutation (SNP) | VAF 113/228 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.743); called by muse, mutect2, varscan2
- FAM187A | c.617A>G p.K206R | Missense Mutation (SNP) | VAF 4/64 reads (6%) | SIFT tolerated (0.6); PolyPhen benign (0); called by muse, mutect2
- FAM241A | c.176A>T p.H59L | Missense Mutation (SNP) | VAF 24/72 reads (33%) | SIFT tolerated (0.16); PolyPhen benign (0.117); called by muse, varscan2
- FANCM | c.1423G>C p.D475H | Missense Mutation (SNP) | VAF 64/114 reads (56%) | SIFT tolerated (0.14); PolyPhen benign (0.013); called by muse, varscan2
- FBN1 | c.4747T>A p.S1583T | Missense Mutation (SNP) | VAF 58/212 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- FCRL1 | c.263C>A p.A88E | Missense Mutation (SNP) | VAF 103/155 reads (66%) | SIFT deleterious (0.02); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- FIGNL1 | c.761del p.N254Ifs*21 | Frame Shift Del (DEL) | VAF 51/115 reads (44%) | called by mutect2, pindel, varscan2
- FLG | c.5392del p.R1798Efs*36 | Frame Shift Del (DEL) | VAF 241/729 reads (33%) | called by mutect2, pindel, varscan2
- FREM3 | c.5320T>A p.W1774R | Missense Mutation (SNP) | VAF 82/197 reads (42%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.453); called by muse, mutect2, varscan2
- FZD10 | c.1696A>T p.T566S | Missense Mutation (SNP) | VAF 64/111 reads (58%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FZD4 | c.1577G>T p.W526L | Missense Mutation (SNP) | VAF 148/345 reads (43%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.968); called by muse, mutect2, varscan2
- GABRG1 | c.737C>A p.S246* | Nonsense Mutation (SNP) | VAF 44/137 reads (32%) | called by muse, mutect2, varscan2
- GHRHR | c.224C>A p.T75N | Missense Mutation (SNP) | VAF 180/306 reads (59%) | SIFT tolerated (0.1); PolyPhen benign (0.259); called by muse, mutect2, varscan2
- GIMAP2 | c.409G>A p.A137T | Missense Mutation (SNP) | VAF 86/226 reads (38%) | SIFT deleterious (0.04); PolyPhen benign (0.305); called by muse, mutect2, varscan2
- GIP | c.287C>A p.A96D | Missense Mutation (SNP) | VAF 31/194 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); called by muse, mutect2, varscan2
- GIT2 | c.79G>C p.G27R | Missense Mutation (SNP) | VAF 78/114 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GJB2 | c.388G>T p.G130C | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GLYATL3 | c.220G>A p.A74T | Missense Mutation (SNP) | VAF 30/86 reads (35%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.657); called by muse, mutect2, varscan2
- GORASP1 | c.1276G>T p.E426* | Nonsense Mutation (SNP) | VAF 94/104 reads (90%) | called by muse, mutect2, varscan2
- GRIA3 | c.784C>A p.H262N | Missense Mutation (SNP) | VAF 130/151 reads (86%) | SIFT tolerated (0.2); PolyPhen benign (0.022); called by muse, mutect2, varscan2
- GRIA4 | c.1015T>A p.W339R | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- GRM8 | c.2086C>G p.L696V | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT tolerated (0.58); PolyPhen possibly damaging (0.456); called by muse, mutect2, varscan2
- HCLS1 | c.446C>A p.S149Y | Missense Mutation (SNP) | VAF 147/186 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- HDAC7 | c.646G>T p.E216* (on ENST00000427332; = p.E255* on NM_015401.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 8/31 reads (26%) | called by muse, mutect2, varscan2
- HDLBP | c.1457A>G p.D486G | Missense Mutation (SNP) | VAF 18/104 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- HDX | c.1103A>T p.N368I | Missense Mutation (SNP) | VAF 35/45 reads (78%) | SIFT deleterious (0.01); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- HERPUD2 | c.79A>C p.S27R | Missense Mutation (SNP) | VAF 118/233 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.417); called by muse, mutect2, varscan2
- HFM1 | c.1985C>A p.T662N | Missense Mutation (SNP) | VAF 62/77 reads (81%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.858); called by muse, mutect2, varscan2
- HFM1 | c.873+2T>A p.X291_splice | Splice Site (SNP) | VAF 49/57 reads (86%) | called by muse, mutect2, varscan2
- HGF | c.1085C>A p.S362* | Nonsense Mutation (SNP) | VAF 127/284 reads (45%) | called by muse, mutect2, varscan2
- HIC1 | c.251T>A p.L84Q (on ENST00000322941 / NM_001098202.1; = p.L65Q on NM_006497.4) | Missense Mutation (SNP) | VAF 77/113 reads (68%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- IFI16 | c.1810G>T p.V604L (on ENST00000295809 / NM_001364867.2; = p.V548L on NM_005531.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 14/416 reads (3%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.898); called by muse, mutect2
- IGHV1-45 | c.290_291del p.T97Sfs*11 | Frame Shift Del (DEL) | VAF 30/208 reads (14%) | called by pindel, varscan2
- IL17REL | c.568G>A p.A190T | Missense Mutation (SNP) | VAF 50/268 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2, varscan2
- INMT | c.710A>T p.H237L | Missense Mutation (SNP) | VAF 53/184 reads (29%) | SIFT tolerated (0.65); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- INO80E | c.22G>A p.E8K | Missense Mutation (SNP) | VAF 215/356 reads (60%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- IRS2 | c.2555G>C p.S852T | Missense Mutation (SNP) | VAF 38/49 reads (78%) | SIFT tolerated (0.45); PolyPhen benign (0.046); called by muse, mutect2, varscan2
- ITGA4 | c.1340-2A>T p.X447_splice | Splice Site (SNP) | VAF 19/90 reads (21%) | called by muse, mutect2, varscan2
- KANSL3 | c.214A>G p.I72V | Missense Mutation (SNP) | VAF 30/56 reads (54%) | SIFT tolerated (0.65); PolyPhen benign (0); called by muse, mutect2
- KAT2A | c.1405C>T p.P469S | Missense Mutation (SNP) | VAF 22/88 reads (25%) | SIFT tolerated (0.08); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- KCNK10 | c.1204G>T p.A402S | Missense Mutation (SNP) | VAF 82/149 reads (55%) | SIFT tolerated, low confidence (0.99); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- KDM2A | c.1435C>T p.P479S | Missense Mutation (SNP) | VAF 31/157 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2
- KEAP1 | c.324G>T p.K108N | Missense Mutation (SNP) | VAF 136/159 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- KIAA1549 | c.5179G>T p.E1727* | Nonsense Mutation (SNP) | VAF 41/91 reads (45%) | called by muse, mutect2, varscan2
- KIAA1549 | c.5178G>T p.Q1726H | Missense Mutation (SNP) | VAF 42/94 reads (45%) | SIFT tolerated (0.05); PolyPhen benign (0); called by muse, mutect2, varscan2
- KIF26A | c.4465G>T p.G1489W | Missense Mutation (SNP) | VAF 12/54 reads (22%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.715); called by muse, mutect2, varscan2
- KIF26B | c.3616C>A p.R1206S | Missense Mutation (SNP) | VAF 83/355 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- KLHL30 | c.524C>A p.P175H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.721); called by muse, mutect2
- KPNB1 | c.783T>G p.F261L | Missense Mutation (SNP) | VAF 26/145 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.391); called by muse, mutect2, varscan2
- KRT76 | c.189C>G p.S63R | Missense Mutation (SNP) | VAF 289/451 reads (64%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- KRTAP2-1 | c.211G>T p.E71* | Nonsense Mutation (SNP) | VAF 50/228 reads (22%) | called by muse, mutect2
- LOXL1 | c.1478A>G p.K493R | Missense Mutation (SNP) | VAF 12/41 reads (29%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- LPCAT1 | c.830A>C p.Y277S | Missense Mutation (SNP) | VAF 29/122 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.675); called by muse, mutect2, varscan2
- LRATD2 | c.129G>T p.E43D | Missense Mutation (SNP) | VAF 191/361 reads (53%) | SIFT tolerated (0.41); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- LRP1B | c.2321T>A p.L774Q | Missense Mutation (SNP) | VAF 20/82 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- LRRIQ1 | c.2089G>C p.V697L | Missense Mutation (SNP) | VAF 26/119 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MAP10 | c.1380G>T p.Q460H | Missense Mutation (SNP) | VAF 50/136 reads (37%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- MAP3K1 | c.883G>A p.G295S | Missense Mutation (SNP) | VAF 60/403 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MAP3K8 | c.717G>T p.K239N | Missense Mutation (SNP) | VAF 119/200 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.142); called by muse, mutect2, varscan2
- MAP3K8 | c.718G>T p.G240* | Nonsense Mutation (SNP) | VAF 119/200 reads (60%) | called by muse, mutect2, varscan2
- MARK4 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 43/66 reads (65%) | SIFT deleterious (0); PolyPhen possibly damaging (0.751); called by muse, mutect2, varscan2
- MCM2 | c.2563C>G p.Q855E | Missense Mutation (SNP) | VAF 28/183 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MPPED2 | c.237C>A p.D79E | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- MSTO1 | c.437C>T p.P146L | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.29); PolyPhen benign (0.001); called by mutect2, varscan2
- MUC16 | c.26410T>G p.L8804V | Missense Mutation (SNP) | VAF 7/129 reads (5%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.105); called by muse, mutect2
- MYBPC1 | c.825G>T p.E275D (on ENST00000550270 / NM_206820.2; = p.E300D on NM_002465.4) | Missense Mutation (SNP) | VAF 44/287 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- MYH1 | c.4130C>A p.T1377N | Missense Mutation (SNP) | VAF 105/142 reads (74%) | SIFT tolerated (0.15); PolyPhen benign (0.011); called by muse, mutect2, varscan2
- MYH4 | c.3395C>T p.S1132F | Missense Mutation (SNP) | VAF 146/191 reads (76%) | SIFT deleterious (0.03); PolyPhen benign (0.285); called by muse, mutect2, varscan2
- N4BP2 | c.3379G>A p.D1127N | Missense Mutation (SNP) | VAF 23/203 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- NEK6 | c.490C>T p.H164Y | Missense Mutation (SNP) | VAF 163/209 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NELL2 | c.2447T>A p.L816Q | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- NEU4 | c.464C>A p.A155D (on ENST00000391969 / NM_001167602.3; = p.A167D on NM_080741.4) | Missense Mutation (SNP) | VAF 58/96 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- NID1 | c.1277T>A p.V426D | Missense Mutation (SNP) | VAF 30/74 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NIPSNAP3A | c.355G>A p.A119T | Missense Mutation (SNP) | VAF 140/170 reads (82%) | SIFT tolerated (0.15); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- NLRP13 | c.443T>C p.L148P | Missense Mutation (SNP) | VAF 97/115 reads (84%) | SIFT tolerated (0.3); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOL9 | c.1150G>A p.E384K | Missense Mutation (SNP) | VAF 12/38 reads (32%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.526); called by muse, mutect2, varscan2
- NOTCH4 | c.200C>A p.P67H | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.903); called by muse, mutect2, varscan2
- NPY2R | c.788G>T p.R263M | Missense Mutation (SNP) | VAF 47/109 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NTSR2 | c.858del p.R287Afs*56 | Frame Shift Del (DEL) | VAF 22/56 reads (39%) | called by mutect2, pindel
- NUP58 | c.684G>T p.K228N | Missense Mutation (SNP) | VAF 36/50 reads (72%) | SIFT tolerated (0.19); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- OAT | c.917G>T p.C306F | Missense Mutation (SNP) | VAF 76/201 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- OBSCN | c.15773A>T p.Q5258L | Missense Mutation (SNP) | VAF 41/89 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- OCA2 | c.430G>T p.V144L | Missense Mutation (SNP) | VAF 78/125 reads (62%) | SIFT tolerated, low confidence (0.5); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR10A6 | c.764C>A p.A255D | Missense Mutation (SNP) | VAF 23/102 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- OR11L1 | c.122G>T p.G41V | Missense Mutation (SNP) | VAF 52/220 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- OR2AK2 | c.61G>T p.G21C | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- OR8J1 | c.586G>T p.E196* | Nonsense Mutation (SNP) | VAF 7/12 reads (58%) | called by muse, mutect2
- OTOGL | c.6733A>G p.M2245V (on ENST00000547103; = p.M2236V on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0); called by muse, mutect2, varscan2
- PAPPA2 | c.5079G>T p.E1693D | Missense Mutation (SNP) | VAF 27/129 reads (21%) | SIFT tolerated (0.17); PolyPhen benign (0.36); called by muse, mutect2, varscan2
- PCDH15 | c.2498C>A p.P833Q | Missense Mutation (SNP) | VAF 58/218 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.985); called by muse, mutect2, varscan2
- PCDHA12 | c.407G>T p.R136M | Missense Mutation (SNP) | VAF 192/240 reads (80%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.326); called by muse, varscan2
- PCDHA5 | c.676C>A p.Q226K | Missense Mutation (SNP) | VAF 55/133 reads (41%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- PCDHB4 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 96/105 reads (91%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCSK2 | c.1033G>T p.E345* | Nonsense Mutation (SNP) | VAF 187/231 reads (81%) | called by muse, mutect2, varscan2
- PDE11A | c.579G>T p.K193N | Missense Mutation (SNP) | VAF 44/344 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.881); called by muse, mutect2, varscan2
- PDE6A | c.1217G>T p.R406L | Missense Mutation (SNP) | VAF 105/292 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PDLIM7 | c.1145A>T p.E382V | Missense Mutation (SNP) | VAF 35/110 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGBD1 | c.339G>T p.E113D | Missense Mutation (SNP) | VAF 13/38 reads (34%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- PHF3 | c.2189+5G>T | Splice Region (SNP) | VAF 32/47 reads (68%) | called by muse, mutect2, varscan2
- PIK3CD | c.1242+1G>T p.X414_splice | Splice Site (SNP) | VAF 216/246 reads (88%) | called by muse, mutect2, varscan2
- PITPNM1 | c.1462G>T p.A488S | Missense Mutation (SNP) | VAF 99/193 reads (51%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- PLCD4 | c.1732A>C p.N578H | Missense Mutation (SNP) | VAF 66/96 reads (69%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.593); called by muse, mutect2, varscan2
- PLPPR4 | c.1912T>A p.S638T | Missense Mutation (SNP) | VAF 161/185 reads (87%) | SIFT deleterious (0.04); PolyPhen benign (0.428); called by muse, mutect2, varscan2
- POLR2B | c.1549-2A>T p.X517_splice | Splice Site (SNP) | VAF 18/50 reads (36%) | called by muse, varscan2
- POU5F1B | c.173G>C p.W58S | Missense Mutation (SNP) | VAF 64/172 reads (37%) | SIFT deleterious (0); PolyPhen benign (0.258); called by muse, mutect2, varscan2
- PPARG | c.1286T>A p.L429Q (on ENST00000287820 / NM_015869.5; = p.L399Q on NM_005037.7) | Missense Mutation (SNP) | VAF 290/352 reads (82%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.846); called by muse, mutect2, varscan2
- PPFIA2 | c.302C>A p.P101Q | Missense Mutation (SNP) | VAF 5/28 reads (18%) | SIFT tolerated (0.73); PolyPhen possibly damaging (0.736); called by muse, mutect2
- PPP1R2B | c.36G>T p.K12N | Missense Mutation (SNP) | VAF 162/261 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- PRG4 | c.3795T>A p.G1265= | Splice Region (SNP) | VAF 127/211 reads (60%) | called by muse, mutect2, varscan2
- PRKACB | c.1029del p.K343Nfs*17 | Frame Shift Del (DEL) | VAF 77/121 reads (64%) | called by mutect2, pindel, varscan2
- PRKD1 | c.76G>T p.A26S | Missense Mutation (SNP) | VAF 13/62 reads (21%) | SIFT tolerated, low confidence (0.72); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- PRPF6 | c.295G>T p.E99* | Nonsense Mutation (SNP) | VAF 45/468 reads (10%) | called by muse, mutect2
- PRPSAP1 | c.838A>T p.I280F | Missense Mutation (SNP) | VAF 39/226 reads (17%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.983); called by muse, mutect2, varscan2
- PRUNE2 | c.5608G>T p.V1870L | Missense Mutation (SNP) | VAF 91/121 reads (75%) | SIFT tolerated (0.29); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSMC1 | c.1177G>T p.A393S | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- PTPRD | c.1713G>T p.R571S | Missense Mutation (SNP) | VAF 109/129 reads (84%) | SIFT tolerated (0.29); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- PTPRE | c.1660G>A p.E554K | Missense Mutation (SNP) | VAF 12/44 reads (27%) | SIFT deleterious (0.02); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- PTPRZ1 | c.5284T>C p.Y1762H | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2, varscan2
- RBM20 | c.1054C>A p.P352T | Missense Mutation (SNP) | VAF 60/109 reads (55%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RBM38 | c.537C>G p.Y179* | Nonsense Mutation (SNP) | VAF 137/538 reads (25%) | called by muse, mutect2, varscan2
- RFPL4AL1 | c.499G>T p.V167L | Missense Mutation (SNP) | VAF 402/554 reads (73%) | SIFT deleterious (0.05); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- RIMS4 | c.307G>T p.A103S | Missense Mutation (SNP) | VAF 17/101 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.223); called by muse, mutect2, varscan2
- RNF208 | c.466A>T p.R156W | Missense Mutation (SNP) | VAF 179/208 reads (86%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- RPS6KC1 | c.697A>T p.K233* | Nonsense Mutation (SNP) | VAF 58/158 reads (37%) | called by muse, mutect2, varscan2
- RYR2 | c.5666C>A p.P1889H | Missense Mutation (SNP) | VAF 23/61 reads (38%) | SIFT tolerated (0.29); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- SDK2 | c.1225C>A p.L409M | Missense Mutation (SNP) | VAF 12/60 reads (20%) | SIFT tolerated (0.12); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- SEC61G | c.27G>T p.E9D | Missense Mutation (SNP) | VAF 80/148 reads (54%) | SIFT tolerated (0.57); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- SERPINC1 | c.1151C>A p.P384Q | Missense Mutation (SNP) | VAF 116/176 reads (66%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.843); called by muse, mutect2, varscan2
- SETD2 | c.4607G>T p.G1536V | Missense Mutation (SNP) | VAF 55/67 reads (82%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- SI | c.3939A>T p.R1313S | Missense Mutation (SNP) | VAF 69/197 reads (35%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.758); called by muse, varscan2
- SI | c.3409G>T p.D1137Y | Missense Mutation (SNP) | VAF 169/215 reads (79%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SIM1 | c.2252C>A p.P751Q | Missense Mutation (SNP) | VAF 32/92 reads (35%) | SIFT tolerated, low confidence (0.62); PolyPhen benign (0.001); called by muse, varscan2
- SIX3 | c.702C>A p.S234R | Missense Mutation (SNP) | VAF 36/223 reads (16%) | SIFT tolerated (0.76); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- SKI | c.262G>T p.G88W | Missense Mutation (SNP) | VAF 237/281 reads (84%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SKI | c.1934_1935dup p.Q646Gfs*28 | Frame Shift Ins (INS) | VAF 26/193 reads (13%) | called by mutect2, pindel, varscan2
- SLC2A4RG | c.722_732del p.F241* | Frame Shift Del (DEL) | VAF 17/73 reads (23%) | called by mutect2, pindel, varscan2
- SLC9A1 | c.1545G>T p.K515N | Missense Mutation (SNP) | VAF 194/233 reads (83%) | SIFT deleterious (0.04); PolyPhen benign (0.423); called by muse, mutect2, varscan2
- SLIT2 | c.524G>C p.R175P | Missense Mutation (SNP) | VAF 57/111 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- SLIT3 | c.3449C>T p.A1150V | Missense Mutation (SNP) | VAF 49/72 reads (68%) | SIFT tolerated (0.4); PolyPhen benign (0.216); called by muse, mutect2, varscan2
- SMS | c.1061dup p.L354Ffs*12 | Frame Shift Ins (INS) | VAF 25/46 reads (54%) | called by mutect2, pindel, varscan2
- SMURF2 | c.1122G>T p.Q374H | Missense Mutation (SNP) | VAF 63/241 reads (26%) | SIFT tolerated (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SOX5 | c.2130G>T p.Q710H | Missense Mutation (SNP) | VAF 44/227 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.1); called by muse, mutect2, varscan2
- SP4 | c.175G>C p.G59R | Missense Mutation (SNP) | VAF 15/55 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SPATA31A1 | c.2729C>A p.P910H | Missense Mutation (SNP) | VAF 42/224 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.939); called by mutect2, varscan2
- SPATA31A3 | c.440C>G p.P147R | Missense Mutation (SNP) | VAF 261/1069 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SPATA31A3 | c.290T>A p.L97Q | Missense Mutation (SNP) | VAF 36/42 reads (86%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); called by mutect2, varscan2
- SPATA31A6 | c.2717C>A p.P906H | Missense Mutation (SNP) | VAF 186/385 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- SPATA5 | c.2329A>T p.R777W | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- SPATC1 | c.540C>A p.S180R | Missense Mutation (SNP) | VAF 66/161 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- SRRM2 | c.6958G>T p.A2320S | Missense Mutation (SNP) | VAF 60/118 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.021); called by muse, mutect2, varscan2
- STARD13 | c.614G>T p.G205V (on ENST00000336934 / NM_001243476.3; = p.G87V on NM_052851.3) | Missense Mutation (SNP) | VAF 40/59 reads (68%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- STARD9 | c.12802G>T p.A4268S | Missense Mutation (SNP) | VAF 45/158 reads (28%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); called by muse, mutect2, varscan2
- STIP1 | c.920G>T p.G307V | Missense Mutation (SNP) | VAF 25/115 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SYNE1 | c.14588G>T p.G4863V (on ENST00000367255 / NM_182961.4; = p.G4792V on NM_033071.3) | Missense Mutation (SNP) | VAF 33/118 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- SYNGR1 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 240/277 reads (87%) | SIFT tolerated (0.66); PolyPhen benign (0); called by muse, mutect2, varscan2
- TAS2R39 | c.638T>G p.F213C | Missense Mutation (SNP) | VAF 9/268 reads (3%) | SIFT tolerated (0.24); PolyPhen benign (0.007); called by muse, mutect2
- TBC1D32 | c.449G>T p.S150I | Missense Mutation (SNP) | VAF 21/43 reads (49%) | SIFT tolerated (0.13); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- TEX10 | c.1960del p.I654Sfs*6 | Frame Shift Del (DEL) | VAF 51/101 reads (50%) | called by mutect2, pindel, varscan2
- TEX15 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 39/114 reads (34%) | SIFT deleterious, low confidence (0); called by muse, mutect2, varscan2
- THBS3 | c.257A>T p.E86V | Missense Mutation (SNP) | VAF 112/427 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- TMCO1 | c.562G>T p.D188Y (on ENST00000612311 / NM_001256164.1; = p.D137Y on NM_019026.6) | Missense Mutation (SNP) | VAF 24/388 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TMEM132E | c.1844G>T p.S615I (on ENST00000321639; = p.S705I on NM_001304438.2) | Missense Mutation (SNP) | VAF 8/32 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS6 | c.740T>G p.M247R | Missense Mutation (SNP) | VAF 28/193 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0); called by muse, mutect2, varscan2
- TMPRSS7 | c.1306C>G p.H436D (on ENST00000452346; = p.H310D on NM_001042575.2) | Missense Mutation (SNP) | VAF 43/45 reads (96%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.529); called by muse, mutect2, varscan2
- TNFAIP6 | c.232+1G>T p.X78_splice | Splice Site (SNP) | VAF 38/82 reads (46%) | called by muse, mutect2, varscan2
- TNFRSF11B | c.1093C>A p.L365I | Missense Mutation (SNP) | VAF 176/279 reads (63%) | SIFT tolerated (0.22); PolyPhen benign (0.416); called by muse, mutect2, varscan2
- TNFSF18 | c.426C>A p.N142K | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.599); called by muse, mutect2, varscan2
- TNKS1BP1 | c.2564A>T p.Y855F | Missense Mutation (SNP) | VAF 74/203 reads (36%) | SIFT tolerated (0.15); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- TNN | c.2986C>T p.P996S | Missense Mutation (SNP) | VAF 170/260 reads (65%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- TOP2B | c.584G>T p.S195I (on ENST00000264331 / NM_001330700.2; = p.S190I on NM_001068.3) | Missense Mutation (SNP) | VAF 13/126 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TPH1 | c.871C>T p.Q291* | Nonsense Mutation (SNP) | VAF 156/322 reads (48%) | called by muse, mutect2, varscan2
- TRAK2 | c.1831G>C p.E611Q | Missense Mutation (SNP) | VAF 33/241 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TRBV4-2 | c.46G>T p.A16S | Missense Mutation (SNP) | VAF 57/334 reads (17%) | SIFT tolerated (0.13); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- TRH | c.500G>T p.W167L | Missense Mutation (SNP) | VAF 94/213 reads (44%) | SIFT tolerated (0.07); PolyPhen benign (0.019); called by muse, mutect2, varscan2
- TRPC3 | c.2576A>T p.Y859F (on ENST00000379645 / NM_001366479.2; = p.Y786F on NM_003305.2) | Missense Mutation (SNP) | VAF 29/83 reads (35%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TSG101 | c.535C>T p.P179S | Missense Mutation (SNP) | VAF 22/144 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TTN | c.33779C>A p.P11260H (on ENST00000591111; = p.P10333H on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/91 reads (20%) | PolyPhen possibly damaging (0.799); called by muse, mutect2, varscan2
- TTN | c.31458G>T p.E10486D (on ENST00000591111; = p.E9559D on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/115 reads (17%) | PolyPhen benign (0.022); called by muse, mutect2, varscan2
- TYR | c.1569C>G p.S523R | Missense Mutation (SNP) | VAF 65/531 reads (12%) | SIFT tolerated (0.26); PolyPhen benign (0.036); called by muse, mutect2, varscan2
- UGT1A4 | c.371T>C p.L124P | Missense Mutation (SNP) | VAF 42/282 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.603); called by muse, mutect2, varscan2
- USP29 | c.611A>G p.Q204R | Missense Mutation (SNP) | VAF 71/87 reads (82%) | SIFT tolerated (0.25); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- USP5 | c.2549_2555del p.I850Tfs*25 (on ENST00000229268 / NM_001098536.2; = p.I827Tfs*25 on NM_003481.3 and 2 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 46/177 reads (26%) | called by mutect2, pindel, varscan2
- UTP4 | c.1205G>T p.G402V | Missense Mutation (SNP) | VAF 185/238 reads (78%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VCAN | c.4421C>A p.T1474N | Missense Mutation (SNP) | VAF 226/338 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.243); called by muse, mutect2, varscan2
- VWA2 | c.1147G>T p.G383C | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- VWA3A | c.1394T>C p.V465A | Missense Mutation (SNP) | VAF 49/124 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); called by muse, mutect2, varscan2
- VWA3B | c.1283C>A p.P428Q | Missense Mutation (SNP) | VAF 15/104 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- VWA3B | c.2616C>A p.H872Q | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- VWA5B1 | c.2559C>A p.H853Q | Missense Mutation (SNP) | VAF 149/174 reads (86%) | SIFT tolerated (0.21); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- WASH6P | c.1333G>T p.E445* | Nonsense Mutation (SNP) | VAF 109/616 reads (18%) | called by muse, mutect2, varscan2
- WASHC5 | c.2880G>T p.Q960H | Missense Mutation (SNP) | VAF 151/693 reads (22%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.991); called by muse, mutect2, varscan2
- WDR89 | c.849T>A p.H283Q | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- XKR6 | c.1673C>A p.T558N | Missense Mutation (SNP) | VAF 100/214 reads (47%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.915); called by muse, mutect2, varscan2
- ZC3H11A | c.985A>G p.K329E | Missense Mutation (SNP) | VAF 90/176 reads (51%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); called by muse, mutect2, varscan2
- ZEB2 | c.331+7G>C | Splice Region (SNP) | VAF 8/132 reads (6%) | called by muse, mutect2
- ZFP36L2 | c.1372A>T p.S458C | Missense Mutation (SNP) | VAF 22/169 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.615); called by muse, mutect2, varscan2
- ZNF182 | c.199+1G>T p.X67_splice | Splice Site (SNP) | VAF 32/196 reads (16%) | called by muse, mutect2, varscan2
- ZNF215 | c.778G>T p.G260* | Nonsense Mutation (SNP) | VAF 20/80 reads (25%) | called by muse, varscan2
- ZNF254 | c.508A>C p.N170H | Missense Mutation (SNP) | VAF 9/47 reads (19%) | SIFT deleterious (0); PolyPhen benign (0.127); called by muse, mutect2, varscan2
- ZNF354C | c.220G>T p.E74* | Nonsense Mutation (SNP) | VAF 73/245 reads (30%) | called by muse, mutect2, varscan2
- ZNF735 | c.56G>T p.R19I | Missense Mutation (SNP) | VAF 58/143 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- ZNF804A | c.264G>T p.K88N | Missense Mutation (SNP) | VAF 51/77 reads (66%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZSWIM3 | c.1592T>C p.V531A | Missense Mutation (SNP) | VAF 144/234 reads (62%) | SIFT tolerated (0.18); PolyPhen benign (0.044); called by muse, mutect2, varscan2
- ZZZ3 | c.-52+1G>T | Splice Site (SNP) | VAF 13/16 reads (81%) | called by muse, varscan2
- ABLIM3 | c.1083C>T p.Y361= | Silent (SNP) | VAF 18/38 reads (47%) | catalogued as rs536555002, COSV58639856; called by muse, mutect2, varscan2
- ACSM2A | c.759C>A p.A253= (on ENST00000219054; = p.A174= on NM_001308169.2) | Silent (SNP) | VAF 14/32 reads (44%) | called by muse, mutect2, varscan2
- ADAM23 | c.1278A>G p.A426= | Silent (SNP) | VAF 14/122 reads (11%) | called by muse, mutect2, varscan2
- ADGRB3 | c.3585C>A p.A1195= | Silent (SNP) | VAF 6/49 reads (12%) | called by mutect2, varscan2
- ALDH1A3 | c.657G>T p.L219= | Silent (SNP) | VAF 82/136 reads (60%) | called by muse, mutect2, varscan2
- ANHX | c.342G>T p.A114= | Silent (SNP) | VAF 90/298 reads (30%) | catalogued as COSV69293910; called by muse, varscan2
- ANTXRL | c.1212G>A p.P404= | Silent (SNP) | VAF 9/68 reads (13%) | catalogued as rs1343231779; called by muse, mutect2
- AVPR1A | c.1251A>C p.S417= | Silent (SNP) | VAF 15/112 reads (13%) | called by muse, varscan2
- BAG5 | c.438G>T p.R146= | Silent (SNP) | VAF 166/248 reads (67%) | called by muse, mutect2, varscan2
- BMP4 | c.615C>T p.V205= | Silent (SNP) | VAF 65/294 reads (22%) | called by muse, mutect2, varscan2
- C5 | c.3939C>T p.I1313= | Silent (SNP) | VAF 127/157 reads (81%) | catalogued as rs774839896, COSV56326041; called by muse, mutect2, varscan2
- CAND1 | c.2337G>T p.L779= | Silent (SNP) | VAF 23/139 reads (17%) | called by muse, mutect2, varscan2
- CBLN4 | c.594G>T p.V198= | Silent (SNP) | VAF 53/142 reads (37%) | called by muse, mutect2, varscan2
- CCT2 | c.1473G>T p.L491= | Silent (SNP) | VAF 34/116 reads (29%) | called by muse, mutect2, varscan2
- CD36 | c.1327C>T p.L443= | Silent (SNP) | VAF 94/232 reads (41%) | called by muse, mutect2, varscan2
- CD93 | c.993C>T p.P331= | Silent (SNP) | VAF 6/39 reads (15%) | called by muse, mutect2
- CD99 | c.60C>A p.A20= | Silent (SNP) | VAF 22/103 reads (21%) | called by muse, mutect2, varscan2
- CDC42BPA | c.4185C>T p.L1395= (on ENST00000334218 / NM_001366019.2; = p.L1382= on NM_003607.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 43/84 reads (51%) | called by muse, mutect2, varscan2
- CDC42BPB | c.2613G>A p.L871= | Silent (SNP) | VAF 24/96 reads (25%) | called by muse, mutect2, varscan2
- CDH23 | c.3678G>T p.T1226= | Silent (SNP) | VAF 95/164 reads (58%) | called by muse, mutect2, varscan2
- CFAP61 | c.621G>A p.L207= | Silent (SNP) | VAF 22/152 reads (14%) | called by muse, mutect2, varscan2
- CHL1 | c.351C>A p.I117= | Silent (SNP) | VAF 55/70 reads (79%) | catalogued as COSV56590118; called by muse, mutect2, varscan2
- CLMN | c.2979C>A p.L993= | Silent (SNP) | VAF 45/85 reads (53%) | catalogued as COSV100112343; called by muse, mutect2, varscan2
- CSMD2 | c.10197C>A p.S3399= | Silent (SNP) | VAF 143/169 reads (85%) | catalogued as COSV53899257; called by muse, mutect2, varscan2
- CYP19A1 | c.1131C>A p.A377= | Silent (SNP) | VAF 59/210 reads (28%) | catalogued as rs1220827475; called by muse, mutect2, varscan2
- DAPK2 | c.933C>T p.V311= | Silent (SNP) | VAF 57/123 reads (46%) | catalogued as rs759815702, COSV56043534; called by muse, mutect2, varscan2
- DBX2 | c.210C>G p.G70= | Silent (SNP) | VAF 62/96 reads (65%) | called by muse, varscan2
- DIRAS2 | c.141G>C p.V47= | Silent (SNP) | VAF 132/166 reads (80%) | called by muse, mutect2, varscan2
- DMXL2 | c.427C>T p.L143= | Silent (SNP) | VAF 16/40 reads (40%) | called by muse, mutect2, varscan2
- DNAH11 | c.10503G>A p.Q3501= | Silent (SNP) | VAF 91/158 reads (58%) | called by muse, mutect2, varscan2
- DNAH9 | c.3984C>T p.N1328= | Silent (SNP) | VAF 122/149 reads (82%) | catalogued as rs193103626, COSV99304522; called by muse, mutect2, varscan2
- DOCK2 | c.3744C>A p.T1248= | Silent (SNP) | VAF 140/229 reads (61%) | called by muse, mutect2, varscan2
- DSCAML1 | c.330G>T p.A110= (on ENST00000321322; = p.A50= on NM_020693.4) | Silent (SNP) | VAF 5/30 reads (17%) | called by muse, mutect2
- EPOR | c.471C>T p.D157= | Silent (SNP) | VAF 36/175 reads (21%) | catalogued as rs776430873; called by muse, mutect2, varscan2
- ERC2 | c.993G>A p.R331= | Silent (SNP) | VAF 46/57 reads (81%) | catalogued as rs762428429; called by muse, mutect2, varscan2
- F2RL2 | c.604C>A p.R202= | Silent (SNP) | VAF 75/325 reads (23%) | called by muse, mutect2, varscan2
- FAM71F2 | c.543C>T p.T181= | Silent (SNP) | VAF 59/179 reads (33%) | catalogued as rs1258235266; called by muse, mutect2, varscan2
- FAT1 | c.6111G>T p.T2037= | Silent (SNP) | VAF 38/96 reads (40%) | catalogued as COSV71673122; called by muse, mutect2, varscan2
- FLNC | c.1461G>A p.K487= | Silent (SNP) | VAF 92/262 reads (35%) | catalogued as rs759126217, COSV57949485; called by muse, mutect2, varscan2
- FOXN3 | c.1431G>T p.T477= (on ENST00000261302; = p.T455= on NM_005197.4) | Silent (SNP) | VAF 39/72 reads (54%) | catalogued as rs1433671424; called by muse, mutect2, varscan2
- GAA | c.1416C>G p.T472= | Silent (SNP) | VAF 32/85 reads (38%) | catalogued as rs368492669; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GATA1 | c.507C>A p.S169= | Silent (SNP) | VAF 155/173 reads (90%) | called by muse, mutect2, varscan2
- GDF5 | c.1485G>T p.V495= | Silent (SNP) | VAF 23/157 reads (15%) | called by muse, mutect2, varscan2
- GHR | c.1554G>A p.P518= | Silent (SNP) | VAF 40/131 reads (31%) | catalogued as rs144046221; called by muse, mutect2, varscan2
- GPHN | c.1014G>A p.P338= (on ENST00000315266 / NM_001377519.1; = p.P371= on NM_020806.5) | Silent (SNP) | VAF 28/156 reads (18%) | catalogued as rs770812117; called by muse, mutect2, varscan2
- GRID1 | c.1695G>T p.V565= | Silent (SNP) | VAF 53/295 reads (18%) | called by muse, mutect2, varscan2
- GRIK4 | c.2160C>T p.F720= | Silent (SNP) | VAF 46/251 reads (18%) | catalogued as rs1433577978; called by muse, mutect2, varscan2
- GRP | c.435G>T p.L145= | Silent (SNP) | VAF 20/144 reads (14%) | called by muse, mutect2, varscan2
- H2BC9 | c.315G>A p.G105= | Silent (SNP) | VAF 37/204 reads (18%) | catalogued as rs765281161; called by muse, mutect2, varscan2
- HAO1 | c.267C>T p.D89= | Silent (SNP) | VAF 9/78 reads (12%) | catalogued as rs138052675; called by muse, mutect2, varscan2
- HTR2A | c.528C>T p.A176= | Silent (SNP) | VAF 85/132 reads (64%) | called by muse, mutect2, varscan2
- IGKV1-12 | c.153T>A p.I51= | Silent (SNP) | VAF 140/456 reads (31%) | catalogued as rs766581389; called by muse, mutect2, varscan2
- IL17RE | c.93G>T p.L31= | Silent (SNP) | VAF 51/135 reads (38%) | catalogued as rs749474945; called by muse, mutect2, varscan2
- ITPKC | c.294G>T p.A98= | Silent (SNP) | VAF 69/522 reads (13%) | called by muse, mutect2, varscan2
- JCAD | c.183G>T p.A61= | Silent (SNP) | VAF 195/300 reads (65%) | catalogued as COSV64760159; called by muse, mutect2, varscan2
- KCNB1 | c.1407G>T p.G469= | Silent (SNP) | VAF 42/69 reads (61%) | called by muse, mutect2, varscan2
- KCNK13 | c.84G>A p.V28= | Silent (SNP) | VAF 38/134 reads (28%) | called by muse, mutect2, varscan2
- KEAP1 | c.1173C>T p.S391= | Silent (SNP) | VAF 19/30 reads (63%) | called by muse, mutect2, varscan2
- KIF26B | c.747C>A p.P249= | Silent (SNP) | VAF 111/379 reads (29%) | called by muse, mutect2, varscan2
- KIN | c.231A>T p.L77= | Silent (SNP) | VAF 109/158 reads (69%) | called by muse, mutect2, varscan2
- KLHL14 | c.714C>A p.L238= | Silent (SNP) | VAF 30/156 reads (19%) | called by muse, mutect2, varscan2
- KMT2C | c.1059C>A p.L353= | Silent (SNP) | VAF 23/381 reads (6%) | called by muse, mutect2
- LY6H | c.75C>A p.G25= | Silent (SNP) | VAF 24/208 reads (12%) | called by muse, mutect2, varscan2
- LYN | c.723G>A p.E241= | Silent (SNP) | VAF 150/235 reads (64%) | catalogued as rs1250183139, COSV70205381; called by muse, mutect2, varscan2
- MAP4K3 | c.1893G>T p.G631= | Silent (SNP) | VAF 19/146 reads (13%) | called by muse, mutect2, varscan2
- MAPK4 | c.1683G>T p.L561= | Silent (SNP) | VAF 23/213 reads (11%) | called by muse, mutect2, varscan2
- MBD3L1 | c.93C>A p.S31= | Silent (SNP) | VAF 94/125 reads (75%) | called by muse, mutect2, varscan2
- MC5R | c.210C>A p.P70= | Silent (SNP) | VAF 26/72 reads (36%) | called by muse, mutect2, varscan2
- MORN5 | c.447C>T p.D149= | Silent (SNP) | VAF 20/170 reads (12%) | catalogued as rs748669612; called by muse, mutect2, varscan2
- MTR | c.1098A>T p.G366= | Silent (SNP) | VAF 98/271 reads (36%) | called by muse, mutect2, varscan2
- MYL12A | c.300T>C p.D100= | Silent (SNP) | VAF 24/60 reads (40%) | called by muse, mutect2, varscan2
- MYT1L | c.2715G>C p.T905= | Silent (SNP) | VAF 76/125 reads (61%) | called by muse, mutect2, varscan2
- NAT8 | c.603C>T p.F201= | Silent (SNP) | VAF 45/158 reads (28%) | called by muse, mutect2, varscan2
- NBPF11 | c.252G>A p.E84= | Silent (SNP) | VAF 105/913 reads (12%) | called by muse, mutect2, varscan2
- NCAPG | c.39C>G p.A13= | Silent (SNP) | VAF 7/49 reads (14%) | called by muse, mutect2, varscan2
- NDST3 | c.2457C>T p.C819= | Silent (SNP) | VAF 33/107 reads (31%) | called by muse, mutect2, varscan2
- NKX3-2 | c.654C>T p.V218= | Silent (SNP) | VAF 27/88 reads (31%) | called by muse, mutect2, varscan2
- NOTCH4 | c.201C>A p.P67= | Silent (SNP) | VAF 15/37 reads (41%) | catalogued as COSV66683058; called by muse, mutect2, varscan2
- OBSCN | c.1572G>A p.R524= | Silent (SNP) | VAF 49/122 reads (40%) | called by muse, mutect2, varscan2
- OR1C1 | c.372G>A p.V124= | Silent (SNP) | VAF 160/246 reads (65%) | catalogued as rs1261004971; called by muse, mutect2, varscan2
- OR1D2 | c.189G>T p.L63= | Silent (SNP) | VAF 192/253 reads (76%) | called by muse, mutect2, varscan2
- OR2B3 | c.69A>C p.L23= | Silent (SNP) | VAF 27/121 reads (22%) | called by muse, mutect2, varscan2
- OR2T12 | c.840C>A p.T280= | Silent (SNP) | VAF 59/394 reads (15%) | called by muse, mutect2, varscan2
- OR5L1 | c.828G>T p.V276= | Silent (SNP) | VAF 58/154 reads (38%) | catalogued as rs201671558, COSV61735625; called by muse, mutect2, varscan2
- OR5T1 | c.712C>T p.L238= | Silent (SNP) | VAF 108/232 reads (47%) | catalogued as COSV57302228; called by muse, varscan2
- PCDHB8 | c.1875G>T p.V625= | Silent (SNP) | VAF 456/709 reads (64%) | called by muse, varscan2
- PCDHGA1 | c.2148G>A p.L716= | Silent (SNP) | VAF 167/409 reads (41%) | catalogued as COSV65296577; called by muse, mutect2, varscan2
- PCDHGB1 | c.2361C>T p.A787= | Silent (SNP) | VAF 152/187 reads (81%) | catalogued as rs1255621963; called by muse, mutect2, varscan2
- PDIA5 | c.969T>C p.H323= | Silent (SNP) | VAF 91/109 reads (83%) | catalogued as rs1336433194; called by muse, mutect2, varscan2
- PDZRN3 | c.1122C>A p.S374= | Silent (SNP) | VAF 60/105 reads (57%) | called by muse, mutect2, varscan2
- PLCL2 | c.889A>C p.R297= (on ENST00000615277 / NM_001144382.2; = p.R171= on NM_015184.5) | Silent (SNP) | VAF 102/129 reads (79%) | catalogued as COSV101196630; called by muse, mutect2, varscan2
- PLXNC1 | c.2898C>A p.T966= | Silent (SNP) | VAF 16/129 reads (12%) | called by muse, mutect2, varscan2
- PSTPIP2 | c.345A>G p.Q115= | Silent (SNP) | VAF 125/190 reads (66%) | called by muse, varscan2
- PTPRN2 | c.2181C>A p.T727= | Silent (SNP) | VAF 66/129 reads (51%) | catalogued as COSV67040470; called by muse, mutect2, varscan2
- RGSL1 | c.525G>A p.L175= | Silent (SNP) | VAF 54/89 reads (61%) | called by muse, mutect2, varscan2
- RNF165 | c.276C>T p.D92= | Silent (SNP) | VAF 36/157 reads (23%) | catalogued as COSV53974161; called by muse, mutect2, varscan2
- RP1 | c.864G>T p.L288= | Silent (SNP) | VAF 68/126 reads (54%) | called by muse, mutect2, varscan2
- SELENON | c.1356G>T p.L452= | Silent (SNP) | VAF 144/173 reads (83%) | called by muse, mutect2, varscan2
- SIGLEC8 | c.45G>A p.K15= | Silent (SNP) | VAF 81/99 reads (82%) | called by muse, mutect2, varscan2
- SLC12A1 | c.1728G>T p.L576= | Silent (SNP) | VAF 32/134 reads (24%) | called by muse, mutect2, varscan2
- SLC13A1 | c.1170A>G p.L390= | Silent (SNP) | VAF 10/103 reads (10%) | catalogued as rs113144170; called by muse, mutect2, varscan2
- SLC22A25 | c.621G>T p.G207= | Silent (SNP) | VAF 78/189 reads (41%) | called by muse, mutect2, varscan2
- SLC27A6 | c.300C>G p.S100= | Silent (SNP) | VAF 42/53 reads (79%) | catalogued as rs1343106951; called by muse, mutect2, varscan2
- SLC34A2 | c.1230C>G p.P410= | Silent (SNP) | VAF 126/382 reads (33%) | called by muse, mutect2, varscan2
- SLC9A4 | c.444C>T p.T148= | Silent (SNP) | VAF 40/279 reads (14%) | catalogued as rs780159923, COSV54836401; called by muse, mutect2, varscan2
- SORCS1 | c.394C>T p.L132= | Silent (SNP) | VAF 162/241 reads (67%) | catalogued as rs1565125920; called by muse, mutect2, varscan2
- SSTR4 | c.1095C>A p.P365= | Silent (SNP) | VAF 33/56 reads (59%) | called by muse, mutect2, varscan2
- TAAR2 | c.507G>C p.S169= (on ENST00000367931 / NM_001033080.1; = p.S124= on NM_014626.3) | Silent (SNP) | VAF 64/128 reads (50%) | catalogued as COSV51578788; called by muse, mutect2, varscan2
- TEKT5 | c.606G>A p.G202= | Silent (SNP) | VAF 22/117 reads (19%) | catalogued as rs1485394004; called by muse, mutect2, varscan2
- TG | c.3981C>A p.A1327= | Silent (SNP) | VAF 188/466 reads (40%) | called by muse, mutect2, varscan2
- TNFAIP3 | c.2292C>G p.A764= | Silent (SNP) | VAF 21/41 reads (51%) | called by muse, mutect2, varscan2
- TSNARE1 | c.858G>T p.G286= | Silent (SNP) | VAF 150/329 reads (46%) | catalogued as COSV56178885; called by muse, mutect2, varscan2
- TXNRD2 | c.126C>T p.L42= | Silent (SNP) | VAF 174/450 reads (39%) | catalogued as COSV57632880; called by muse, mutect2, varscan2
- TYSND1 | c.489C>T p.S163= | Silent (SNP) | VAF 138/215 reads (64%) | called by muse, mutect2, varscan2
- UNC80 | c.5460T>C p.A1820= | Silent (SNP) | VAF 24/132 reads (18%) | catalogued as rs1216220763; called by muse, mutect2, varscan2
- ZFP2 | c.690A>T p.T230= | Silent (SNP) | VAF 78/101 reads (77%) | called by muse, mutect2, varscan2
- ZNF292 | c.7095A>G p.V2365= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as rs926718720; called by muse, varscan2
- ZNF488 | c.36G>T p.P12= | Silent (SNP) | VAF 27/49 reads (55%) | called by muse, mutect2, varscan2
- ZNF677 | c.1527T>C p.H509= | Silent (SNP) | VAF 19/144 reads (13%) | called by muse, mutect2, varscan2
- ZNF746 | c.1449G>T p.P483= | Silent (SNP) | VAF 64/154 reads (42%) | catalogued as rs1046097709; called by muse, mutect2, varscan2
- ZNF862 | c.1791G>T p.T597= | Silent (SNP) | VAF 127/368 reads (35%) | catalogued as rs1392389552, COSV56224132, COSV56224977; called by muse, mutect2, varscan2
- AAK1 | c.*9609del | 3'UTR (DEL) | VAF 20/90 reads (22%) | catalogued as rs767719947; called by mutect2, varscan2
- AARS2 | c.*22A>T | 3'UTR (SNP) | VAF 41/266 reads (15%) | called by muse, mutect2, varscan2
- ABCB8 | c.147-592C>T | Intron (SNP) | VAF 62/127 reads (49%) | called by muse, mutect2, varscan2
- ABCC8 | c.1333-45del | Intron (DEL) | VAF 53/128 reads (41%) | called by mutect2, pindel, varscan2
- AC062028.1 | n.855G>T | RNA (SNP) | VAF 14/148 reads (9%) | called by muse, mutect2
- ACBD5 | chr10:27196839 G>A | 3'Flank (SNP) | VAF 44/410 reads (11%) | called by muse, mutect2, varscan2
- ACSL5 | c.-96A>T | 5'UTR (SNP) | VAF 32/114 reads (28%) | called by muse, mutect2, varscan2
- ADAMTS13 | c.987+70A>G | Intron (SNP) | VAF 37/162 reads (23%) | called by muse, mutect2, varscan2
- ADGRE4P | n.2541G>T | RNA (SNP) | VAF 61/76 reads (80%) | called by muse, mutect2, varscan2
- AGAP14P | n.1812C>A | RNA (SNP) | VAF 159/459 reads (35%) | called by muse, mutect2, varscan2
- AGPAT4 | c.348+4950C>T | Intron (SNP) | VAF 45/149 reads (30%) | catalogued as rs1288259187; called by muse, mutect2, varscan2
- ALDOA | c.1161+25G>T | Intron (SNP) | VAF 52/243 reads (21%) | called by muse, mutect2
- ANKRD7 | c.*32del | 3'UTR (DEL) | VAF 42/111 reads (38%) | called by mutect2, pindel, varscan2
- ARL15 | c.463-64835G>C | Intron (SNP) | VAF 16/71 reads (23%) | called by muse, mutect2, varscan2
- ATIC | c.19+135G>T | Intron (SNP) | VAF 9/41 reads (22%) | catalogued as rs966731641; called by muse, mutect2, varscan2
- BAGE2 | n.210C>A | RNA (SNP) | VAF 30/300 reads (10%) | called by muse, mutect2
- BMP5 | c.*25A>G | 3'UTR (SNP) | VAF 27/129 reads (21%) | called by muse, mutect2, varscan2
- C20orf173 | c.-141C>A | 5'UTR (SNP) | VAF 56/195 reads (29%) | called by muse, mutect2, varscan2
- CASR | c.*26G>T | 3'UTR (SNP) | VAF 155/199 reads (78%) | called by muse, mutect2, varscan2
- CCDC74B | c.296-154T>G | Intron (SNP) | VAF 10/170 reads (6%) | called by muse, mutect2
- CEP41 | c.*4328C>T | 3'UTR (SNP) | VAF 72/157 reads (46%) | called by muse, mutect2, varscan2
- CICP28 | chr7:56811920 G>A | 3'Flank (SNP) | VAF 28/197 reads (14%) | catalogued as rs1305977523; called by muse, mutect2, varscan2
- CICP28 | chr7:56811921 G>T | 3'Flank (SNP) | VAF 28/198 reads (14%) | called by muse, mutect2, varscan2
- COLGALT2 | c.833-17C>A | Intron (SNP) | VAF 41/69 reads (59%) | catalogued as rs773441027; called by muse, mutect2, varscan2
- CRYGS | c.*11G>A | 3'UTR (SNP) | VAF 130/167 reads (78%) | called by muse, mutect2, varscan2
- CSHL1 | c.191-78A>T | Intron (SNP) | VAF 229/328 reads (70%) | called by muse, mutect2, varscan2
- CYP11B1 | c.*22C>G | 3'UTR (SNP) | VAF 193/387 reads (50%) | called by muse, mutect2, varscan2
- DNAJB14 | c.306-1511A>G | Intron (SNP) | VAF 13/37 reads (35%) | called by muse, varscan2
- DNM1L | c.*1455T>G | 3'UTR (SNP) | VAF 9/86 reads (10%) | catalogued as rs1279047930; called by muse, mutect2, varscan2
- DPYS | c.*83C>A | 3'UTR (SNP) | VAF 98/348 reads (28%) | called by muse, mutect2, varscan2
- EFHC1 | c.723+157G>T | Intron (SNP) | VAF 118/395 reads (30%) | called by muse, mutect2, varscan2
- ERGIC3 | chr20:35559156 C>T | 3'Flank (SNP) | VAF 14/93 reads (15%) | catalogued as rs1568875399; called by muse, varscan2
- ETFB | c.-32G>A | 5'UTR (SNP) | VAF 50/231 reads (22%) | catalogued as rs764342231; called by muse, mutect2, varscan2
- GUSBP10 | n.86G>T | RNA (SNP) | VAF 110/178 reads (62%) | called by muse, mutect2, varscan2
- HIKESHI | c.269-10838A>T | Intron (SNP) | VAF 79/175 reads (45%) | called by muse, mutect2, varscan2
- HIRA | c.*179T>G | 3'UTR (SNP) | VAF 94/127 reads (74%) | called by muse, mutect2, varscan2
- HMGA2 | c.250-36550C>A | Intron (SNP) | VAF 13/21 reads (62%) | called by muse, varscan2
- HSPA7 | n.183G>A | RNA (SNP) | VAF 212/465 reads (46%) | catalogued as rs1557873983; called by muse, mutect2, varscan2
- JUP | c.*3G>T | 3'UTR (SNP) | VAF 21/27 reads (78%) | called by muse, mutect2, varscan2
- KANK2 | c.1249+23G>T | Intron (SNP) | VAF 103/195 reads (53%) | called by muse, mutect2, varscan2
- LGALS4 | c.-2C>A | 5'UTR (SNP) | VAF 24/145 reads (17%) | catalogued as COSV99669625; called by muse, mutect2, varscan2
- LINC01036 | n.293C>A | RNA (SNP) | VAF 51/299 reads (17%) | called by muse, mutect2, varscan2
- LINC01193 | n.1445C>A | RNA (SNP) | VAF 32/76 reads (42%) | catalogued as rs1368919144; called by mutect2, varscan2
- LINC02090 | n.166G>A | RNA (SNP) | VAF 85/103 reads (83%) | catalogued as rs1460842688; called by muse, mutect2, varscan2
- LY6E-DT | n.281C>T | RNA (SNP) | VAF 61/173 reads (35%) | called by muse, mutect2, varscan2
- MAPK9 | c.122+482G>A | Intron (SNP) | VAF 50/362 reads (14%) | called by muse, mutect2, varscan2
- OR3A4P | n.602A>T | RNA (SNP) | VAF 125/183 reads (68%) | called by muse, mutect2, varscan2
- PCLAF | c.290+3028G>A | Intron (SNP) | VAF 30/64 reads (47%) | called by muse, mutect2, varscan2
- PDXDC1 | chr16:14974899 A>G | 5'Flank (SNP) | VAF 42/294 reads (14%) | catalogued as rs1359546292; called by muse, mutect2, varscan2
- PEPD | c.-13G>T | 5'UTR (SNP) | VAF 112/428 reads (26%) | called by muse, mutect2, varscan2
- PKD1L2 | c.2778+60del | Intron (DEL) | VAF 127/214 reads (59%) | called by mutect2, pindel, varscan2
- PRORY | n.538C>A | RNA (SNP) | VAF 100/120 reads (83%) | called by muse, mutect2, varscan2
- PTPRN2 | c.113-42939C>A | Intron (SNP) | VAF 81/181 reads (45%) | catalogued as COSV66039168; called by muse, mutect2, varscan2
- RGS20 | c.510+1446_510+1463del | Intron (DEL) | VAF 90/193 reads (47%) | called by mutect2, varscan2
- RHOBTB2 | chr8:22994567 G>A | 5'Flank (SNP) | VAF 47/102 reads (46%) | called by muse, mutect2, varscan2
- RPL28 | c.206-603C>T | Intron (SNP) | VAF 84/108 reads (78%) | called by muse, mutect2, varscan2
- RPN2 | c.1883+1740G>A | Intron (SNP) | VAF 47/193 reads (24%) | catalogued as rs981854576; called by muse, mutect2, varscan2
- RPUSD3 | chr3:9844035 C>T | 5'Flank (SNP) | VAF 25/89 reads (28%) | called by muse, mutect2, varscan2
- SCLY | c.802-155G>A | Intron (SNP) | VAF 9/75 reads (12%) | catalogued as rs1445084463; called by muse, mutect2, varscan2
- SLC1A2 | c.-30T>A | 5'UTR (SNP) | VAF 24/83 reads (29%) | called by muse, mutect2, varscan2
- SLC35B1 | c.216-327A>G | Intron (SNP) | VAF 11/105 reads (10%) | catalogued as rs753771286; called by muse, mutect2, varscan2
- SNORD115-37 | n.3G>T | RNA (SNP) | VAF 18/26 reads (69%) | catalogued as rs752321199; called by muse, mutect2, varscan2
- SPATA31C1 | n.1290C>T | RNA (SNP) | VAF 376/468 reads (80%) | catalogued as rs1564139822; called by muse, mutect2, varscan2
- SYNE3 | c.-1C>T | 5'UTR (SNP) | VAF 13/46 reads (28%) | called by muse, mutect2, varscan2
- SYT14 | c.*1108G>C | 3'UTR (SNP) | VAF 35/63 reads (56%) | called by muse, mutect2, varscan2
- SYT14 | chr1:210163189 A>G | 3'Flank (SNP) | VAF 61/215 reads (28%) | called by muse, mutect2, varscan2
- TAOK2 | chr16:29989648 GGCAGTACAA>C | 3'Flank (DEL) | VAF 63/377 reads (17%) | called by pindel, varscan2*
- TBC1D9B | c.2915-117G>A | Intron (SNP) | VAF 29/36 reads (81%) | catalogued as COSV100783466; called by muse, mutect2, varscan2
- TDRD5 | c.2160+2149T>C | Intron (SNP) | VAF 101/136 reads (74%) | called by muse, mutect2, varscan2
- TMEM59L | c.664+205G>A | Intron (SNP) | VAF 15/303 reads (5%) | catalogued as rs866816122; called by muse, mutect2
- TTC6 | chr14:37792396 G>T | 5'Flank (SNP) | VAF 25/111 reads (23%) | called by muse, mutect2, varscan2
- TUBB7P | n.1252G>T | RNA (SNP) | VAF 52/123 reads (42%) | called by muse, mutect2, varscan2
- TUBB7P | n.1251G>T | RNA (SNP) | VAF 52/126 reads (41%) | called by muse, mutect2, varscan2
- UQCRB | c.*948A>T | 3'UTR (SNP) | VAF 66/245 reads (27%) | called by muse, mutect2, varscan2
- ZNF419 | c.199+181G>C | Intron (SNP) | VAF 47/61 reads (77%) | called by muse, mutect2, varscan2
